Gene-level copy-number profile of tumor specimen C3N-01200-03 from CPTAC case C3N-01200, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.3 years (20,550 days).
Specimen C3N-01200-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d868c8a2-a82c-445f-8811-7b8ca650f5b6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01200-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/b8f1bd4c-052a-4f40-875d-ae6ef5e02fe0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 11,868; copy number 2: 40,293; copy number 3: 6,082; copy number 4: 117; copy number 5: 2; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,190,003–61,453,030, 7 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:61,615,835–61,627,683, 1 gene: FAM242D.
- chr10:87,751,512–88,259,372, 10 genes: ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.
- chr17:7,839,904–7,932,123, 11 genes (within-gene range 0–1): KDM6B, TMEM88, NAA38, CYB5D1, AC104581.4, CHD3, SCARNA21, RNF227, KCNAB3, AC104581.2, TRAPPC1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–14,409, 1 gene, copy number 5: DDX11L1.
- chr3:130,048,143–130,055,920, 1 gene, copy number 5: AC083906.4.
- chr10:133,778,246–133,778,699, 2 genes, copy number 8: RPL23AP60, BX322534.1.

Autosomal genes at a single copy (total copy number 1): 11,842. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
